Somatic mutation profile of tumor specimen TCGA-W3-AA1R-06A (aliquot TCGA-W3-AA1R-06A-11D-A397-08) from TCGA case TCGA-W3-AA1R, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 73.7 years (26,906 days).
Specimen TCGA-W3-AA1R-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3bd5845d-b067-413d-b32f-29fd725118e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W3-AA1R-10A (Blood Derived Normal), aliquot TCGA-W3-AA1R-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8dd5df48-a002-4a2c-b4f6-c3ba304c73c8

The open-access MAF lists 2,125 somatic variants for this specimen: 1,384 protein-altering or splice-affecting, 690 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,236, Silent 690, Nonsense Mutation 87, Intron 25, Splice Region 22, Splice Site 19, RNA 14, Translation Start Site 6, 3'UTR 6, In Frame Del 5, Frame Shift Del 5, Frame Shift Ins 3.

Variants (750 of 2,125; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/133 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 87/134 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 23/28 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913386, CM983988, COSV58683051, COSV58690307, COSV58692178; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.4930C>T p.R1644* | Nonsense Mutation (SNP) | VAF 32/67 reads (48%) | catalogued as rs140630, CM013931, COSV57331556; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GJB2 | c.598G>A p.G200R | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as rs786204597, CM042712, CM0910079, COSV101241470; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as rs587782350, CM991083, COSV64291511, COSV64305247; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ROBO3 | c.1082G>A p.G361E | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121918270, CM041427, COSV101184923; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN2A | c.3631G>A p.E1211K | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as rs387906684, CM095805, COSV99330257; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.4772G>A p.W1591* (on ENST00000333535 / NM_198056.3; = p.W1590* on NM_000335.5) | Nonsense Mutation (SNP) | VAF 21/53 reads (40%) | catalogued as rs863225273, COSV61140869; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 12/25 reads (48%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AACS | c.473-1G>A p.X158_splice | Splice Site (SNP) | VAF 6/21 reads (29%) | catalogued as COSV99907771; called by muse, mutect2
- ABCA12 | c.5565A>T p.E1855D (on ENST00000272895 / NM_173076.3; = p.E1537D on NM_015657.3) | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.122); catalogued as COSV99788495; called by muse, mutect2
- ABCA12 | c.5563G>A p.E1855K (on ENST00000272895 / NM_173076.3; = p.E1537K on NM_015657.3) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV55956182; called by muse, mutect2
- ABCA13 | c.14234C>T p.P4745L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.541); catalogued as COSV68945827; called by muse, mutect2
- ABCB1 | c.2000C>T p.S667L | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV99712221; called by muse, mutect2, varscan2
- ABCB11 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as rs1324562575, COSV99791574; called by muse, mutect2, varscan2
- ABCC9 | c.4559C>T p.S1520F | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV99684592; called by muse, mutect2, varscan2
- ABHD16A | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1189500747, COSV101013122; called by muse, mutect2, varscan2
- AC013477.1 | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.173); catalogued as COSV99548719; called by muse, mutect2, varscan2
- AC107871.1 | c.121C>T p.H41Y | Missense Mutation (SNP) | VAF 21/64 reads (33%) | PolyPhen benign (0.3); catalogued as COSV100682806; called by muse, mutect2, varscan2
- ACADL | c.329T>C p.I110T | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.649); catalogued as rs140832039; called by muse, mutect2, varscan2
- ACAN | c.2947G>A p.E983K | Missense Mutation (SNP) | VAF 78/202 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as COSV100717106; called by muse, varscan2
- ACE | c.3649G>A p.E1217K | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as COSV99326475; called by muse, varscan2
- ACOX2 | c.569G>A p.W190* | Nonsense Mutation (SNP) | VAF 40/116 reads (34%) | catalogued as COSV100250015; called by muse, mutect2, varscan2
- ACSL1 | c.1134C>G p.F378L | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV99860372; called by muse, mutect2
- ACSL5 | c.1648G>A p.G550R (on ENST00000354273; = p.G606R on NM_016234.3) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61133501; called by muse, mutect2, varscan2
- ACSM2B | c.1571C>A p.T524N | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV100312340; called by muse, mutect2, varscan2
- ACSM4 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs368493928; called by muse, mutect2, varscan2
- ACSS2 | c.205T>A p.F69I | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.842); catalogued as COSV99489598; called by muse, mutect2, varscan2
- ACTRT2 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs548864585, COSV65760870, COSV65760924; called by muse, mutect2, varscan2
- ACVR1 | c.1289C>T p.P430L | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55122294; called by muse, mutect2, varscan2
- ACVR2B | c.1102G>T p.E368* | Nonsense Mutation (SNP) | VAF 26/58 reads (45%) | catalogued as COSV100754168; called by muse, mutect2, varscan2
- ADAM19 | c.854G>A p.W285* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99976218; called by muse, mutect2
- ADAM22 | c.1489C>T p.Q497* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as rs1303294171, COSV99715827; called by muse, mutect2, varscan2
- ADAM8 | c.1632C>T p.Y544= | Splice Region (SNP) | VAF 7/10 reads (70%) | catalogued as rs1465898762, COSV101291612; called by muse, mutect2, varscan2
- ADAMDEC1 | c.807A>C p.E269D | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99835858; called by muse, mutect2, varscan2
- ADAMTS12 | c.4333G>A p.E1445K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as rs1372671716, COSV100710323; called by muse, mutect2
- ADAMTS12 | c.3320C>T p.S1107F | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as rs755541287, COSV61272212; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4604G>A p.G1535E | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.56); PolyPhen benign (0.062); catalogued as COSV54461873; called by muse, varscan2
- ADCY5 | c.2420C>T p.S807F | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.411); catalogued as COSV100567339; called by muse, mutect2, varscan2
- ADCY8 | c.3709G>A p.E1237K | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.052); catalogued as COSV53930169; called by muse, mutect2, varscan2
- ADD2 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs781930613, COSV52464563; called by muse, mutect2, varscan2
- ADD2 | c.168G>A p.M56I | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as COSV100034801; called by muse, mutect2, varscan2
- ADGRF2 | c.759G>A p.W253* (on ENST00000296862 / NM_001368115.2; = p.W185* on NM_153839.7) | Nonsense Mutation (SNP) | VAF 32/74 reads (43%) | catalogued as COSV57291739; called by muse, mutect2, varscan2
- ADGRF2 | c.1006C>T p.P336S (on ENST00000296862 / NM_001368115.2; = p.P268S on NM_153839.7) | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as COSV57292950; called by muse, mutect2, varscan2
- ADGRF4 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99348043; called by muse, mutect2, varscan2
- ADGRG3 | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT tolerated (0.46); PolyPhen benign (0.054); catalogued as rs1157980263, COSV100342089; called by muse, mutect2, varscan2
- ADGRL3 | c.2435C>T p.A812V (on ENST00000506720 / NM_001322402.2; = p.A744V on NM_015236.6) | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as rs371598174; called by muse, mutect2, varscan2
- ADGRV1 | c.3043C>T p.Q1015* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV101315522; called by muse, mutect2, varscan2
- ADGRV1 | c.4085T>A p.M1362K | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV101315523; called by muse, mutect2, varscan2
- ADH1C | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs759025388, COSV72463545; called by muse, mutect2, varscan2
- ADH7 | c.28A>C p.K10Q | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV99265066; called by muse, mutect2, varscan2
- ADK | c.232C>T p.H78Y (on ENST00000286621; = p.H61Y on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV54205636; called by muse, mutect2, varscan2
- AFF2 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 92/123 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV99662044; called by muse, mutect2, varscan2
- AFF2 | c.2728G>A p.E910K | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV99662048; called by muse, mutect2, varscan2
- AFF3 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as COSV57852663; called by muse, varscan2
- AFM | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.742); catalogued as rs1327023385, COSV56922522; called by muse, mutect2, varscan2
- AFP | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs369442700; called by muse, mutect2, varscan2
- AGRN | c.2500C>T p.R834* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as COSV101038600; called by muse, mutect2, varscan2
- AGT | c.1124+2T>C p.X375_splice | Splice Site (SNP) | VAF 136/161 reads (84%) | catalogued as COSV100794218; called by muse, mutect2, varscan2
- AHNAK2 | c.6627C>G p.D2209E | Missense Mutation (SNP) | VAF 72/177 reads (41%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.898); catalogued as rs763729491, COSV100315779, COSV100315950; called by muse, mutect2, varscan2
- AIMP2 | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 107/155 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99773843; called by muse, mutect2, varscan2
- AK9 | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99572355; called by muse, mutect2, varscan2
- AKAP3 | c.2245C>T p.P749S | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.105); catalogued as COSV99961809; called by muse, mutect2, varscan2
- AKAP9 | c.9892C>T p.Q3298* (on ENST00000359028; = p.Q3274* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 19/104 reads (18%) | catalogued as COSV100661941; called by muse, mutect2, varscan2
- AKIP1 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746236246, COSV100214863; called by muse, mutect2, varscan2
- AKNAD1 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 37/49 reads (76%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV100645338; called by muse, mutect2, varscan2
- AL121899.2 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101198386; called by muse, mutect2, varscan2
- AL645922.1 | c.971G>A p.R324K | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.21); catalogued as COSV100190685; called by muse, mutect2, varscan2
- ALCAM | c.1163G>A p.G388E | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1369498196, COSV100064285; called by muse, mutect2, varscan2
- ALG3 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99890774; called by muse, mutect2
- ALPK2 | c.2255C>T p.S752F | Missense Mutation (SNP) | VAF 68/177 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV100864142; called by muse, mutect2, varscan2
- ALS2 | c.1918C>T p.R640* | Nonsense Mutation (SNP) | VAF 76/167 reads (46%) | catalogued as rs1182543397, COSV99968801; called by muse, mutect2, varscan2
- AMY1B | c.1046G>A p.G349E | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100375543; called by mutect2, varscan2
- ANK2 | c.3799G>T p.G1267* | Nonsense Mutation (SNP) | VAF 17/63 reads (27%) | catalogued as COSV52164532; called by muse, mutect2, varscan2
- ANK3 | c.9673G>A p.E3225K | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs867499524, COSV55070593; called by muse, mutect2, varscan2
- ANK3 | c.1312C>T p.H438Y | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99778460; called by muse, mutect2, varscan2
- ANKEF1 | c.884G>A p.G295D | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs941022745, COSV101000986; called by muse, mutect2, varscan2
- ANKRD46 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); catalogued as rs267601678, COSV59513939, COSV59514594; called by muse, mutect2, varscan2
- ANKRD6 | c.1871G>A p.G624E (on ENST00000339746 / NM_001242809.2; = p.G619E on NM_014942.4) | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV100329449; called by muse, mutect2, varscan2
- ANO4 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV100152061; called by muse, mutect2, varscan2
- ANPEP | c.2157+1G>A p.X719_splice | Splice Site (SNP) | VAF 31/96 reads (32%) | catalogued as COSV100262627; called by muse, mutect2, varscan2
- AOC2 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs145007333; called by muse, mutect2, varscan2
- AP1B1 | c.2237C>T p.S746F | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs1397124382, COSV100434400; called by muse, mutect2, varscan2
- APOA5 | c.590G>A p.S197N | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV99911182; called by muse, mutect2, varscan2
- APOB | c.13487G>A p.R4496K | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV51922834, COSV51952204, COSV51952606; called by muse, mutect2, varscan2
- APOB | c.11674C>T p.P3892S | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99263793; called by muse, mutect2, varscan2
- APOB | c.4173G>A p.M1391I | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV51936540; called by muse, mutect2, varscan2
- APOBEC2 | c.68A>G p.N23S | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.01); catalogued as COSV99775299; called by muse, mutect2, varscan2
- ARAP2 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.03); catalogued as COSV58287041; called by muse, mutect2, varscan2
- ARFGEF2 | c.1708A>G p.I570V | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.109); catalogued as COSV100904004; called by muse, mutect2, varscan2
- ARHGAP15 | c.80G>A p.R27K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV54501633, COSV54509102, COSV54524799; called by muse, mutect2, varscan2
- ARHGAP20 | c.1496C>T p.S499F | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99503173; called by muse, mutect2, varscan2
- ARHGAP4 | c.1920C>T p.N640= | Splice Region (SNP) | VAF 10/15 reads (67%) | catalogued as COSV100509419; called by muse, mutect2, varscan2
- ARL4C | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); catalogued as COSV100326779; called by muse, mutect2, varscan2
- ARMC12 | c.664C>T p.L222F (on ENST00000373866 / NM_001286574.2; = p.L249F on NM_145028.5) | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV55362138, COSV99849359; called by muse, mutect2, varscan2
- ARSJ | c.1607C>T p.P536L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs915617859, COSV59537310; called by muse, mutect2, varscan2
- ASAH1 | c.602T>C p.L201S | Missense Mutation (SNP) | VAF 48/66 reads (73%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.814); catalogued as COSV100025530; called by muse, mutect2, varscan2
- ASB15 | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 79/104 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV51926822; called by muse, mutect2, varscan2
- ASZ1 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1343852598, COSV52914933; called by muse, mutect2, varscan2
- ATAD2 | c.1596A>T p.E532D | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99784113; called by muse, mutect2, varscan2
- ATAD2B | c.3538G>A p.E1180K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.769); catalogued as COSV99477025; called by muse, mutect2, varscan2
- ATP10A | c.4325C>T p.S1442F | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as COSV63513953; called by muse, mutect2, varscan2
- ATP10B | c.4142C>T p.T1381I | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV100514186; called by muse, mutect2, varscan2
- ATP10B | c.3248C>T p.S1083F | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV59163962; called by muse, mutect2, varscan2
- ATP11A | c.746T>A p.L249Q | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99367550; called by muse, mutect2, varscan2
- ATP1A4 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 109/130 reads (84%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as COSV100927447, COSV63628166; called by muse, mutect2, varscan2
- ATP6V1G3 | c.268A>G p.K90E | Missense Mutation (SNP) | VAF 49/57 reads (86%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV99810703; called by muse, mutect2, varscan2
- ATP7B | c.3745G>A p.V1249M | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99666082; called by muse, mutect2, varscan2
- ATP7B | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.434); catalogued as COSV99666084; called by muse, mutect2, varscan2
- ATRNL1 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as rs368755603, COSV100746539; called by muse, mutect2, varscan2
- AZGP1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 65/280 reads (23%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.453); catalogued as rs1197405844, COSV52797548; called by muse, mutect2, varscan2
- B3GNT5 | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100191366; called by muse, mutect2, varscan2
- BCAR3 | c.652C>T p.Q218* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as COSV99550296; called by muse, mutect2, varscan2
- BEND4 | c.1319C>T p.S440L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101549716; called by muse, mutect2, varscan2
- BFSP2 | c.25G>T p.D9Y | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs749050992, COSV100183565; called by muse, mutect2, varscan2
- BLNK | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.08); catalogued as COSV99813650; called by muse, mutect2, varscan2
- BNC1 | c.2279C>T p.P760L | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV61757528; called by muse, mutect2, varscan2
- BNC1 | c.2072G>A p.G691E | Missense Mutation (SNP) | VAF 48/85 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs1040425302, COSV100596925; called by muse, mutect2, varscan2
- BNC1 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs200106261, COSV61759322; called by muse, mutect2, varscan2
- BOD1 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as rs1392102392, COSV99603420; called by muse, mutect2, varscan2
- BPIFB4 | c.857G>C p.G286A | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV100971434; called by muse, mutect2, varscan2
- BRPF1 | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57404973; called by muse, mutect2, varscan2
- BSN | c.4466C>T p.P1489L | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV99607373; called by muse, mutect2, varscan2
- BTC | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.796); catalogued as rs1553955659, COSV101201471; called by muse, mutect2
- BTN3A1 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.676); catalogued as COSV99175635; called by muse, mutect2, varscan2
- C12orf45 | c.303A>T p.E101D | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99773976; called by muse, mutect2, varscan2
- C17orf75 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as rs1294424372, COSV99858519; called by muse, mutect2, varscan2
- C19orf57 | c.299G>C p.G100A | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.66); catalogued as COSV100694634; called by muse, mutect2, varscan2
- C3orf56 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 86/243 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.902); catalogued as COSV101228927; called by muse, mutect2, varscan2
- C4B | c.3352C>T p.Q1118* | Nonsense Mutation (SNP) | VAF 63/150 reads (42%) | catalogued as COSV101312145; called by muse, mutect2, varscan2
- C4B | c.3907C>T p.Q1303* | Nonsense Mutation (SNP) | VAF 9/82 reads (11%) | catalogued as COSV101312146; called by muse, mutect2, varscan2
- C4orf17 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100430739; called by muse, mutect2, varscan2
- C6 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as rs866430363, COSV54704541; called by muse, mutect2, varscan2
- C6orf15 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.025); catalogued as COSV99456658; called by muse, mutect2, varscan2
- C9orf131 | c.889G>A p.G297R | Missense Mutation (SNP) | VAF 39/59 reads (66%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs772004608, COSV100397934; called by muse, mutect2, varscan2
- CACNA1C | c.1893G>A p.T631= | Splice Region (SNP) | VAF 12/20 reads (60%) | catalogued as rs1252210096, COSV100215649; called by muse, mutect2, varscan2
- CACNA1D | c.2533C>A p.P845T (on ENST00000350061 / NM_001128840.3; = p.P865T on NM_000720.4) | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV99856684; called by muse, mutect2, varscan2
- CACNA1E | c.2591C>T p.S864F | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as COSV100701304; called by muse, mutect2, varscan2
- CACNA1S | c.3520G>A p.A1174T | Missense Mutation (SNP) | VAF 60/67 reads (90%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.799); catalogued as COSV100754687; called by muse, mutect2, varscan2
- CALR3 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 33/47 reads (70%) | SIFT tolerated (0.19); PolyPhen benign (0.054); catalogued as COSV54168850, COSV99522067; called by muse, mutect2, varscan2
- CAMK4 | c.1271G>A p.G424E | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1463029846, COSV99998377; called by muse, mutect2, varscan2
- CAMKK1 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV99339974; called by muse, mutect2, varscan2
- CAMSAP1 | c.2174C>T p.S725F | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs868268203, COSV100409596; called by muse, mutect2, varscan2
- CAPG | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV99809275; called by muse, mutect2, varscan2
- CAPN6 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 60/70 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60694486; called by muse, mutect2, varscan2
- CAPN7 | c.2122C>T p.Q708* | Nonsense Mutation (SNP) | VAF 19/61 reads (31%) | catalogued as COSV99512574; called by muse, mutect2, varscan2
- CASP10 | c.1282G>A p.D428N (on ENST00000272879 / NM_032974.5; = p.D385N on NM_001230.5) | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.707); catalogued as COSV99628750; called by muse, mutect2, varscan2
- CASR | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV56140331; called by muse, mutect2, varscan2
- CATSPER1 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 52/97 reads (54%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.683); catalogued as rs773984720, COSV56414346; called by muse, mutect2, varscan2
- CATSPERB | c.2815G>A p.E939K | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); catalogued as rs866205134, COSV56428671; called by muse, mutect2, varscan2
- CBLIF | c.1100G>A p.G367D | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99950754; called by muse, mutect2, varscan2
- CBX4 | c.1139C>T p.P380L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1323378448, COSV99490221; called by muse, mutect2, varscan2
- CCDC102B | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.799); catalogued as COSV60144441; called by muse, mutect2, varscan2
- CCDC117 | c.634A>G p.K212E | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99968806; called by muse, mutect2, varscan2
- CCDC141 | c.3649C>T p.P1217S | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55385542; called by muse, mutect2, varscan2
- CCDC30 | c.2374C>T p.P792S (on ENST00000340612; = p.P749S on NM_001080850.3) | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.219); catalogued as COSV100501091; called by muse, mutect2, varscan2
- CCDC39 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs749794148, COSV56478360, COSV99869927; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC68 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as rs761969346, COSV61604542; called by muse, mutect2, varscan2
- CCDC73 | c.148C>T p.H50Y | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs1462940314, COSV58795902; called by muse, mutect2, varscan2
- CCDC83 | c.320G>A p.R107K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.203); catalogued as rs776106187, COSV99721488; called by muse, mutect2, varscan2
- CCDC97 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs752661636, COSV54189810; called by muse, mutect2, varscan2
- CCER1 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.349); catalogued as COSV62648768; called by muse, mutect2, varscan2
- CCNY | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.864); catalogued as COSV99590227; called by muse, mutect2, varscan2
- CCR6 | c.1109C>T p.S370L | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs772577655, COSV100550994; called by muse, mutect2, varscan2
- CCR9 | c.250G>A p.D84N (on ENST00000357632 / NM_031200.3; = p.D72N on NM_006641.4) | Missense Mutation (SNP) | VAF 113/280 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200142278, COSV62939737; called by muse, mutect2, varscan2
- CD163 | c.1660C>T p.L554F | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100775693; called by muse, mutect2, varscan2
- CD207 | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs868927682, COSV101338529; called by mutect2, varscan2
- CD300C | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.725); catalogued as rs779564893, COSV100423186; called by muse, mutect2, varscan2
- CD48 | c.497A>T p.Y166F | Missense Mutation (SNP) | VAF 165/180 reads (92%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV63566467; called by muse, mutect2, varscan2
- CD84 | c.969T>A p.D323E (on ENST00000311224 / NM_001184879.2; = p.D306E on NM_003874.4) | Missense Mutation (SNP) | VAF 80/92 reads (87%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as COSV100245826; called by muse, mutect2, varscan2
- CD9 | c.35A>G p.Y12C | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV50531623; called by muse, mutect2, varscan2
- CD96 | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV51920632; called by muse, varscan2
- CDH18 | c.999+1G>A p.X333_splice | Splice Site (SNP) | VAF 21/45 reads (47%) | catalogued as rs1255101258, COSV99932370; called by muse, mutect2, varscan2
- CDH19 | c.241C>T p.L81F | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100050927, COSV100052353; called by muse, mutect2, varscan2
- CDH20 | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780788767, COSV53003819, COSV99406539; called by muse, mutect2, varscan2
- CDH20 | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs368429600; called by muse, mutect2, varscan2
- CDH23 | c.4339G>A p.D1447N | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV99819045; called by muse, mutect2, varscan2
- CDH23 | c.6218C>T p.T2073I | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV99819047; called by muse, mutect2, varscan2
- CDH6 | c.1571C>T p.S524L | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.066); catalogued as rs202247793, COSV54065357; called by muse, mutect2, varscan2
- CDHR2 | c.2975C>T p.S992F | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs1484593696, COSV99029540; called by muse, mutect2, varscan2
- CDHR3 | c.1703C>T p.P568L | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100487997; called by muse, mutect2, varscan2
- CDHR5 | c.1180-1G>A p.X394_splice | Splice Site (SNP) | VAF 23/45 reads (51%) | catalogued as COSV100363279; called by muse, mutect2, varscan2
- CDON | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.57); PolyPhen benign (0.095); catalogued as COSV99700659; called by muse, mutect2, varscan2
- CECR2 | c.680C>T p.S227F (on ENST00000342247 / NM_001290047.2; = p.S64F on NM_001290046.1) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as rs769221545, COSV99377080; called by muse, mutect2, varscan2
- CELA2B | c.650G>A p.G217D | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1454288649, COSV100423623; called by muse, mutect2, varscan2
- CENPE | c.4813G>A p.E1605K | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV99477077; called by muse, mutect2, varscan2
- CEP126 | c.1582C>T p.P528S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.444); catalogued as COSV99680605; called by muse, mutect2, varscan2
- CEP128 | c.953A>G p.K318R | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT tolerated (0.79); PolyPhen benign (0.086); catalogued as COSV99382849; called by muse, mutect2, varscan2
- CEP128 | c.647T>C p.V216A | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as rs752159735, COSV99382851; called by muse, mutect2, varscan2
- CEP152 | c.2335C>T p.Q779* | Nonsense Mutation (SNP) | VAF 42/83 reads (51%) | catalogued as COSV100358536; called by muse, mutect2, varscan2
- CEP350 | c.3982C>T p.R1328C | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs750054456, COSV62600955; called by muse, mutect2, varscan2
- CEP63 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100132568; called by muse, mutect2, varscan2
- CERKL | c.1446C>T p.F482= (on ENST00000339098 / NM_001030311.2; = p.F456= on NM_201548.5) | Splice Region (SNP) | VAF 16/55 reads (29%) | catalogued as COSV59204972; called by muse, mutect2, varscan2
- CERT1 | c.1160T>C p.L387P (on ENST00000405807 / NM_001130105.1; = p.L259P on NM_005713.3) | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99782840; called by muse, mutect2, varscan2
- CETN1 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59121518; called by muse, mutect2
- CFAP251 | c.2522C>T p.S841F | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as rs1462461418, COSV99995745; called by muse, mutect2, varscan2
- CFAP43 | c.3109G>A p.E1037K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99530409; called by muse, mutect2, varscan2
- CFAP45 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 33/41 reads (80%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); catalogued as COSV100928466; called by muse, mutect2, varscan2
- CFAP65 | c.1361T>C p.L454P | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99838236; called by muse, mutect2, varscan2
- CFHR2 | c.692C>A p.S231* | Nonsense Mutation (SNP) | VAF 79/85 reads (93%) | catalogued as COSV100804254, COSV66381698; called by muse, mutect2, varscan2
- CFHR4 | c.1049C>T p.S350F (on ENST00000367416 / NM_001201551.2; = p.S104F on NM_006684.5) | Missense Mutation (SNP) | VAF 108/122 reads (89%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.92); catalogued as rs1338727661, COSV52229475, COSV99259586; called by muse, mutect2, varscan2
- CGNL1 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs770027591, COSV55566028; called by muse, mutect2, varscan2
- CHAT | c.1507C>T p.Q503* | Nonsense Mutation (SNP) | VAF 27/70 reads (39%) | catalogued as COSV60325219; called by muse, mutect2, varscan2
- CHD6 | c.7291G>A p.E2431K | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.926); catalogued as rs1459301306, COSV100950580; called by muse, mutect2, varscan2
- CHRNA2 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99531910; called by muse, mutect2, varscan2
- CHRND | c.643C>T p.H215Y | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99285533; called by muse, mutect2, varscan2
- CILP | c.1091G>A p.R364K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV99972850, COSV99973827; called by muse, mutect2, varscan2
- CILP2 | c.3259G>A p.G1087S | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs771659906, COSV99364353; called by muse, varscan2
- CLBA1 | c.495C>G p.D165E | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.135); catalogued as COSV101120979; called by muse, mutect2, varscan2
- CLDN14 | c.500G>A p.G167D | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100578413; called by muse, mutect2, varscan2
- CLDN16 | c.110T>C p.L37P | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1268061294, COSV99289968; called by muse, mutect2, varscan2
- CLEC14A | c.783C>G p.N261K | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.121); catalogued as COSV100643500; called by muse, mutect2, varscan2
- CLMN | c.29A>G p.Q10R | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as rs1451792640, COSV100112107; called by muse, mutect2, varscan2
- CMA1 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 62/122 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0.356); catalogued as COSV99157117; called by muse, mutect2, varscan2
- CMYA5 | c.5735G>A p.G1912E | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as rs1339697814, COSV101483860, COSV71404139; called by muse, mutect2, varscan2
- CNGB3 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 55/197 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.233); catalogued as COSV60685142; called by muse, mutect2, varscan2
- CNGB3 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0.037); catalogued as rs1349739824, COSV60686107; called by muse, mutect2, varscan2
- CNTD1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.542); catalogued as rs1158075057, COSV100162041; called by muse, mutect2, varscan2
- CNTN3 | c.2057C>T p.P686L | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55178481, COSV99723368; called by muse, mutect2, varscan2
- CNTN4 | c.1874G>A p.S625N | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868652439, COSV100638864, COSV100639136; called by muse, mutect2, varscan2
- COBL | c.3518C>A p.A1173D | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99471371; called by muse, mutect2
- COBLL1 | c.1033C>T p.P345S (on ENST00000392717; = p.P307S on NM_014900.5) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV99527371; called by muse, mutect2, varscan2
- COL11A2 | c.3830C>T p.P1277L (on ENST00000341947 / NM_080680.3; = p.P1170L on NM_080679.2) | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs777156156, COSV100553483; called by muse, mutect2, varscan2
- COL11A2 | c.2801G>A p.G934E (on ENST00000341947 / NM_080680.3; = p.G827E on NM_080679.2) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1470126287, COSV100553485; called by muse, mutect2, varscan2
- COL14A1 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.325); catalogued as COSV99918111; called by muse, mutect2, varscan2
- COL21A1 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as COSV55158678, COSV99777539; called by muse, mutect2, varscan2
- COL21A1 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs1303517343, COSV55157025, COSV55173062; called by muse, mutect2, varscan2
- COL28A1 | c.1064G>A p.G355E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV68081460, COSV68083278; called by muse, mutect2, varscan2
- COL4A4 | c.3895C>T p.P1299S | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.474); catalogued as COSV100306269; called by muse, mutect2, varscan2
- COL4A4 | c.2146G>A p.E716K | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.012); catalogued as COSV100306271; called by muse, mutect2, varscan2
- COL4A4 | c.1807G>A p.D603N | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs1479512818, COSV100306272; called by muse, mutect2, varscan2
- COL4A4 | c.1806G>A p.G602= | Splice Region (SNP) | VAF 4/14 reads (29%) | catalogued as rs267599230; called by muse, mutect2, varscan2
- COL5A1 | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs868555520, COSV100879558; called by muse, mutect2, varscan2
- COL5A1 | c.4090G>A p.D1364N | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV100879559; called by muse, mutect2, varscan2
- COL6A3 | c.7627C>T p.L2543F | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99796317; called by muse, mutect2, varscan2
- COPZ1 | c.463C>T p.L155F | Missense Mutation (SNP) | VAF 84/229 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.295); catalogued as COSV50431980; called by muse, mutect2, varscan2
- COX8C | c.219G>C p.*73Yext*28 | Nonstop Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as COSV99825990; called by muse, mutect2, varscan2
- CPA5 | c.318G>A p.M106I | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.683); catalogued as COSV100812242; called by muse, mutect2, varscan2
- CPN1 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.029); catalogued as COSV64942256, COSV64942384; called by muse, mutect2, varscan2
- CPSF3 | c.1156A>T p.M386L | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.021); catalogued as COSV99432481; called by muse, mutect2, varscan2
- CR1 | c.4660G>A p.G1554R | Missense Mutation (SNP) | VAF 98/106 reads (92%) | SIFT tolerated (0.26); PolyPhen probably damaging (1); catalogued as rs907980596, COSV65463720; called by muse, mutect2, varscan2
- CRACR2A | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV99364623; called by muse, mutect2, varscan2
- CRB1 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 89/111 reads (80%) | SIFT tolerated (0.08); PolyPhen benign (0.339); catalogued as COSV100958382; called by muse, mutect2, varscan2
- CREB3L3 | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 44/60 reads (73%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs766239768, COSV99313885; called by muse, mutect2, varscan2
- CREB5 | c.646C>T p.L216F (on ENST00000357727 / NM_182898.4; = p.L209F on NM_004904.3) | Missense Mutation (SNP) | VAF 50/73 reads (68%) | SIFT tolerated (0.71); PolyPhen benign (0.017); catalogued as COSV100744181; called by muse, mutect2, varscan2
- CREB5 | c.1121C>T p.P374L (on ENST00000357727 / NM_182898.4; = p.P367L on NM_004904.3) | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63221043; called by muse, mutect2, varscan2
- CREBBP | c.6764C>T p.P2255L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.001); catalogued as rs1191357764, COSV52125093; called by muse, mutect2, varscan2
- CRNKL1 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV55621659; called by muse, mutect2
- CROCC | c.1751A>C p.H584P | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as COSV100978062; called by muse, mutect2
- CROCC | c.5677C>T p.H1893Y | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1316709405, COSV100977592; called by muse, mutect2, varscan2
- CRYBA4 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV100697754, COSV61322943; called by muse, mutect2, varscan2
- CRYBG1 | c.2876C>T p.S959F | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV100954405; called by muse, mutect2, varscan2
- CSMD1 | c.2972G>A p.G991E (on ENST00000520002; = p.G990E on NM_033225.6) | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760328601, COSV100144284; called by muse, varscan2
- CSMD2 | c.9463C>T p.L3155F | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV53913031; called by muse, mutect2
- CSMD2 | c.3933-1G>A p.X1311_splice | Splice Site (SNP) | VAF 12/31 reads (39%) | catalogued as COSV99586383; called by muse, mutect2
- CSMD2 | c.3668T>C p.V1223A | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV99586387; called by muse, mutect2, varscan2
- CSMD2 | c.3343C>T p.P1115S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53961572; called by muse, mutect2, varscan2
- CSMD3 | c.9320C>T p.P3107L (on ENST00000297405 / NM_001363185.1; = p.P2938L on NM_052900.3) | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1289970104, COSV99825641; called by muse, mutect2, varscan2
- CSMD3 | c.5822G>A p.G1941E (on ENST00000297405 / NM_001363185.1; = p.G1837E on NM_052900.3) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52289908; called by muse, mutect2, varscan2
- CSMD3 | c.2999A>G p.Y1000C (on ENST00000297405 / NM_001363185.1; = p.Y896C on NM_052900.3) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99825646; called by muse, varscan2
- CSMD3 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV52116447; called by muse, mutect2, varscan2
- CSNK1D | c.127A>T p.K43* | Nonsense Mutation (SNP) | VAF 47/122 reads (39%) | catalogued as COSV100012179; called by muse, mutect2, varscan2
- CSTF2 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 36/44 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100802904; called by muse, mutect2, varscan2
- CUBN | c.8300C>T p.S2767L | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV100912092; called by muse, mutect2, varscan2
- CWH43 | c.2053G>A p.E685K | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.269); catalogued as COSV56937070; called by muse, mutect2, varscan2
- CXXC1 | c.1354C>A p.H452N | Missense Mutation (SNP) | VAF 79/184 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.534); catalogued as rs1199581248, COSV99495517; called by muse, mutect2, varscan2
- CYB5R1 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 61/69 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1465257097, COSV100579390; called by muse, mutect2, varscan2
- CYP11B2 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.255); catalogued as COSV100010711; called by muse, mutect2, varscan2
- CYP1A2 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757272055, COSV100673856; called by muse, mutect2, varscan2
- CYP26B1 | c.1034T>C p.L345P | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV99134255; called by muse, mutect2, varscan2
- CYP2C19 | c.511G>A p.G171S | Missense Mutation (SNP) | VAF 99/237 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.173); catalogued as COSV100990237, COSV100990280; called by muse, mutect2, varscan2
- CYP2C19 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.11); catalogued as rs867067400, COSV64907708; called by muse, mutect2, varscan2
- CYP2C9 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as rs753338224, COSV99582225; called by muse, mutect2, varscan2
- CYP2C9 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV53246446, COSV99582229; called by muse, mutect2, varscan2
- CYP2C9 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.503); catalogued as COSV99582233; called by muse, mutect2, varscan2
- CYP2J2 | c.1200G>A p.M400I | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV64605876; called by muse, mutect2, varscan2
- CYP4A22 | c.1301C>T p.S434F | Missense Mutation (SNP) | VAF 63/201 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs138826010; called by muse, mutect2, varscan2
- CYP4F12 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.949); catalogued as rs1273708026, COSV61174566; called by muse, mutect2, varscan2
- CYP4F22 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1380468237, COSV99512508; called by muse, mutect2, varscan2
- CYRIA | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 68/176 reads (39%) | catalogued as rs1161086604, COSV100838237; called by muse, varscan2
- DAG1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 28/82 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV100444728; called by muse, mutect2, varscan2
- DAXX | c.1897C>T p.R633W | Missense Mutation (SNP) | VAF 49/207 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs773398360, COSV56472310; called by muse, mutect2, varscan2
- DCC | c.3393G>A p.K1131= | Splice Region (SNP) | VAF 15/31 reads (48%) | catalogued as COSV71427284; called by muse, mutect2, varscan2
- DCDC1 | c.4529G>A p.R1510K (on ENST00000597505 / NM_001367979.1; = p.R617K on NM_020869.3) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100337864; called by muse, mutect2, varscan2
- DCLK3 | c.1275G>A p.M425I | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV101373880; called by muse, mutect2, varscan2
- DCUN1D2 | c.772C>T p.L258F | Missense Mutation (SNP) | VAF 145/384 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.023); catalogued as rs1421212019, COSV100215081; called by muse, mutect2, varscan2
- DDC | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1562983213, COSV100779130; called by muse, mutect2, varscan2
- DEFB116 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.642); catalogued as rs770289014, COSV101269209; called by muse, mutect2, varscan2
- DENND11 | c.469C>T p.L157F | Missense Mutation (SNP) | VAF 28/300 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1017220885, COSV101530693, COSV101530737; called by muse, mutect2
- DENND2A | c.1446G>A p.K482= | Splice Region (SNP) | VAF 35/306 reads (11%) | catalogued as COSV99325581; called by muse, varscan2
- DENND2A | c.1424G>A p.R475K | Missense Mutation (SNP) | VAF 306/398 reads (77%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV99325584; called by muse, varscan2
- DENND2C | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated (0.1); PolyPhen benign (0.113); catalogued as rs746742222, COSV101283892; called by muse, mutect2, varscan2
- DENND2D | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV100718542; called by muse, mutect2, varscan2
- DHCR7 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV100831729; called by muse, mutect2, varscan2
- DHX35 | c.943A>G p.M315V | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV99326456; called by muse, mutect2, varscan2
- DHX36 | c.2606T>C p.V869A | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV100273342; called by muse, mutect2, varscan2
- DIAPH2 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100230919; called by muse, mutect2, varscan2
- DIDO1 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.054); catalogued as COSV56623335, COSV99824865; called by muse, varscan2
- DIDO1 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1283157274, COSV56622596, COSV56632585; called by muse, varscan2
- DIP2A | c.1096A>T p.T366S | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs760624329, COSV100595229; called by muse, varscan2
- DIP2B | c.3673C>T p.P1225S | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); catalogued as COSV99997943; called by muse, mutect2, varscan2
- DLG2 | c.343G>A p.G115R | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99712831; called by muse, mutect2, varscan2
- DLG5 | c.3508C>T p.P1170S | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs1230334386, COSV64948026; called by muse, mutect2, varscan2
- DLGAP2 | c.1292G>A p.R431K | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as rs1486176011, COSV70098792; called by muse, mutect2, varscan2
- DMBT1 | c.6131G>A p.W2044* (on ENST00000338354 / NM_001377530.1; = p.W1287* on NM_004406.3) | Nonsense Mutation (SNP) | VAF 25/57 reads (44%) | catalogued as COSV100351817; called by muse, mutect2, varscan2
- DNAH10 | c.1271C>T p.T424I (on ENST00000409039; = p.T363I on NM_207437.3) | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.187); catalogued as COSV68988084; called by muse, mutect2, varscan2
- DNAH12 | c.1204C>T p.R402W | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs115213778, COSV100244364; called by muse, mutect2, varscan2
- DNAH17 | c.752A>G p.N251S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1325769143, COSV101101526; called by muse, mutect2, varscan2
- DNAH3 | c.6368G>A p.R2123Q | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773079950, COSV54553426; called by muse, mutect2, varscan2
- DNAH5 | c.12536C>T p.S4179F | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV99445444; called by muse, mutect2, varscan2
- DNAH5 | c.7294T>A p.F2432I | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.703); catalogued as COSV99445448; called by muse, mutect2, varscan2
- DNAH5 | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as COSV99445452; called by muse, mutect2, varscan2
- DNAH7 | c.2205G>A p.K735= | Splice Region (SNP) | VAF 13/41 reads (32%) | catalogued as rs758865891, COSV100413935; called by muse, mutect2
- DNAJB13 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV100334437; called by muse, mutect2, varscan2
- DNAJB2 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.247); catalogued as COSV100338842; called by muse, mutect2, varscan2
- DNAJC5B | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV99395445; called by muse, mutect2, varscan2
- DNER | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV59162499; called by muse, mutect2
- DNM3 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 29/33 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100797782; called by muse, mutect2, varscan2
- DNTT | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs760244560, COSV100960437; called by muse, mutect2, varscan2
- DOCK10 | c.4046C>T p.S1349L | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs374472028; called by muse, mutect2, varscan2
- DOCK11 | c.6102+1G>A p.X2034_splice | Splice Site (SNP) | VAF 34/38 reads (89%) | catalogued as COSV99352970; called by muse, mutect2, varscan2
- DOCK4 | c.3268C>T p.H1090Y | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.074); catalogued as COSV69855233; called by muse, mutect2, varscan2
- DOK7 | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.198); catalogued as rs1394492656, COSV100403155; called by muse, mutect2, varscan2
- DPF3 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.05); catalogued as COSV100818424; called by muse, mutect2, varscan2
- DPP6 | c.1641G>A p.M547I (on ENST00000377770 / NM_001364500.2; = p.M485I on NM_001936.5) | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT tolerated (0.4); PolyPhen benign (0.071); catalogued as COSV100123298; called by muse, mutect2, varscan2
- DPPA4 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV59510134; called by muse, mutect2, varscan2
- DRC1 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs778301620, COSV99985043; called by muse, mutect2, varscan2
- DSC3 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100844528; called by muse, mutect2, varscan2
- DSG3 | c.367T>A p.F123I | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99933781; called by muse, mutect2, varscan2
- DUOX2 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV101199531; called by muse, mutect2
- DUS1L | c.788A>T p.H263L | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV100152396; called by muse, mutect2, varscan2
- DUSP16 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1207191880, COSV99962945; called by muse, mutect2, varscan2
- DUSP7 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as rs764525808, COSV99623411; called by muse, mutect2, varscan2
- DYNC1H1 | c.4214C>T p.S1405F | Missense Mutation (SNP) | VAF 114/283 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100794485, COSV64142225; called by muse, mutect2, varscan2
- EFCAB13 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.059); catalogued as rs149684195; called by muse, mutect2, varscan2
- EFEMP1 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs369049569; called by muse, mutect2, varscan2
- EGR4 | c.598G>A p.D200N (on ENST00000545030; = p.D97N on NM_001965.4) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs567529621, COSV101474208; called by muse, varscan2
- EIF2AK4 | c.4511C>T p.S1504F | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV99774108; called by muse, mutect2, varscan2
- ELAPOR2 | c.3058C>T p.Q1020* (on ENST00000450689 / NM_001142749.3; = p.Q853* on NM_152748.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 17/83 reads (20%) | catalogued as rs1346314758, COSV99788236; called by muse, mutect2, varscan2
- ELAVL4 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as COSV100836575; called by muse, mutect2, varscan2
- ELOA2 | c.1199G>A p.G400E | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as COSV55293008; called by muse, mutect2, varscan2
- ENC1 | c.736C>T p.L246F | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.978); catalogued as rs11557041, COSV100187914; called by muse, mutect2, varscan2
- ENOX2 | c.559C>T p.R187C (on ENST00000338144 / NM_001382520.1; = p.R158C on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57647076, COSV57650021; called by muse, mutect2, varscan2
- ENPP1 | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs143771474, CM088010, COSV62938105; called by muse, mutect2, varscan2
- EP400 | c.4278-1G>A p.X1426_splice | Splice Site (SNP) | VAF 16/35 reads (46%) | catalogued as COSV100200501; called by muse, mutect2, varscan2
- EPB41L4A | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99812782; called by muse, mutect2
- EPHA3 | c.286T>C p.Y96H | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as COSV100343068; called by muse, mutect2, varscan2
- EPHA3 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs866025221, COSV60719513, COSV60726782; called by muse, mutect2, varscan2
- EPHA3 | c.2347G>A p.G783R | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60714723; called by muse, mutect2, varscan2
- EPHA4 | c.2842C>T p.Q948* | Nonsense Mutation (SNP) | VAF 35/97 reads (36%) | catalogued as COSV56046169; called by muse, mutect2, varscan2
- EPHA6 | c.1085G>A p.G362E | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV67559561; called by muse, mutect2, varscan2
- EPHA6 | c.2176C>T p.R726C (on ENST00000389672 / NM_001080448.3; = p.R118C on NM_173655.4) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs774266264, COSV67565553; called by muse, mutect2, varscan2
- EPHA8 | c.1940G>A p.G647E | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99384281; called by muse, mutect2, varscan2
- EPPK1 | c.671C>T p.S224L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs374953787; called by muse, mutect2, varscan2
- EPS8L3 | c.1681C>T p.R561C (on ENST00000361965 / NM_133181.4; = p.R531C on NM_024526.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs772599226, COSV62608722; called by muse, mutect2, varscan2
- ERBB2 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.76); PolyPhen benign (0.011); catalogued as rs370514427; called by muse, mutect2, varscan2
- ERBB3 | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV99915888; called by muse, mutect2, varscan2
- ERC2 | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as rs886296459, COSV99881450; called by muse, mutect2, varscan2
- ERG | c.1123G>T p.A375S (on ENST00000398919 / NM_001243428.1; = p.A351S on NM_004449.4) | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55733296, COSV99901229; called by muse, mutect2, varscan2
- ERGIC3 | c.643C>T p.H215Y | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV99650148; called by muse, varscan2
- ERICH3 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.87); catalogued as COSV100445494, COSV58611100; called by muse, mutect2, varscan2
- ERICH5 | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as rs1387190263, COSV100582675; called by muse, mutect2, varscan2
- ESPL1 | c.4981C>T p.L1661F | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99228929; called by muse, mutect2, varscan2
- ETV6 | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV101122393, COSV67154490; called by muse, mutect2, varscan2
- EXOC1 | c.1762C>T p.R588C | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.806); catalogued as rs746493906, COSV62119089, COSV99051309; called by muse, mutect2, varscan2
- EXPH5 | c.5732G>A p.W1911* | Nonsense Mutation (SNP) | VAF 27/35 reads (77%) | catalogued as COSV99761010; called by muse, mutect2, varscan2
- EXPH5 | c.5413G>A p.D1805N | Missense Mutation (SNP) | VAF 35/52 reads (67%) | SIFT tolerated (0.4); PolyPhen benign (0.026); catalogued as rs371341661, COSV56208312; called by muse, mutect2, varscan2
- F5 | c.1299C>T p.I433= | Splice Region (SNP) | VAF 42/54 reads (78%) | catalogued as rs541673477, COSV63121250; called by muse, mutect2, varscan2
- FAM126A | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.011); catalogued as COSV101299988; called by muse, mutect2, varscan2
- FAM135B | c.1616G>A p.R539K | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1461157114, COSV52723837, COSV99419349; called by muse, mutect2, varscan2
- FAM135B | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV52702200; called by muse, mutect2, varscan2
- FAM13C | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.997); catalogued as COSV99512885; called by muse, mutect2, varscan2
- FAM155A | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as COSV65564369; called by muse, mutect2, varscan2
- FAM160A2 | c.213C>A p.N71K | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99791734; called by muse, mutect2, varscan2
- FAM214B | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1375363008, COSV100521186; called by muse, mutect2, varscan2
- FAM234A | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1490461625, COSV100055428; called by muse, mutect2, varscan2
- FAM83D | c.19G>A p.G7S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as rs748094923, COSV99465002; called by muse, mutect2, varscan2
- FAP | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51862265; called by muse, mutect2, varscan2
- FASTKD3 | c.1924G>T p.E642* | Nonsense Mutation (SNP) | VAF 23/52 reads (44%) | catalogued as COSV99242418; called by muse, mutect2, varscan2
- FAT2 | c.8882G>A p.G2961E | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV99941769; called by muse, mutect2, varscan2
- FAT3 | c.1613C>T p.S538F | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0.134); catalogued as COSV53081986; called by muse, mutect2, varscan2
- FAT3 | c.2176G>C p.D726H | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV99962308; called by muse, mutect2, varscan2
- FAT3 | c.11800G>A p.D3934N | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766248015, COSV99962311; called by muse, mutect2, varscan2
- FAT4 | c.5863G>A p.E1955K | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100627313; called by muse, mutect2, varscan2
- FAT4 | c.6493G>A p.E2165K | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58685937; called by muse, mutect2, varscan2
- FAT4 | c.8537G>A p.R2846Q | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs373393333, COSV58673723; called by muse, mutect2, varscan2
- FAT4 | c.13046G>A p.G4349E | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58701359; called by muse, varscan2
- FAT4 | c.13069C>T p.R4357* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV58671941; called by muse, varscan2
- FBF1 | c.2065C>T p.Q689* (on ENST00000586717; = p.Q703* on NM_001319193.1) | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as rs1189890154, COSV100044765; called by muse, mutect2, varscan2
- FBXO7 | c.890T>C p.I297T | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as COSV99832475; called by muse, mutect2, varscan2
- FBXW8 | c.1108C>T p.H370Y (on ENST00000309909; = p.H408Y on NM_012174.1) | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778584640, COSV99997466, COSV99998058; called by muse, mutect2, varscan2
- FCER1A | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 49/58 reads (84%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.905); catalogued as COSV63667713; called by muse, mutect2, varscan2
- FCGBP | c.2578C>T p.R860C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.827); catalogued as rs1310522638; called by muse, mutect2
- FER1L6 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV67548784; called by muse, mutect2, varscan2
- FER1L6 | c.3376T>C p.S1126P | Missense Mutation (SNP) | VAF 75/149 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.133); catalogued as rs1439224304, COSV101205491; called by muse, mutect2, varscan2
- FERMT2 | c.29A>T p.D10V | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV100448721; called by muse, mutect2, varscan2
- FFAR3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 12/54 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.299); catalogued as COSV59908812; called by muse, mutect2, varscan2
- FGA | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100120034, COSV57395699; called by muse, mutect2, varscan2
- FGD4 | c.1428G>A p.M476I | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs777703867, COSV99846787; called by muse, mutect2, varscan2
- FGF14 | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); catalogued as COSV65951022; called by muse, mutect2, varscan2
- FGF17 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.27); PolyPhen benign (0.028); catalogued as rs763956510, COSV100846127; called by muse, mutect2, varscan2
- FGF6 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 9/22 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as rs1263936373, COSV99960153; called by muse, mutect2, varscan2
- FHL1 | c.854G>A p.R285K | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.364); catalogued as COSV61781560; called by muse, mutect2, varscan2
- FHOD3 | c.3968C>T p.S1323F (on ENST00000359247 / NM_001281739.3; = p.S1340F on NM_025135.5) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV57171514; called by muse, mutect2, varscan2
- FILIP1 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 49/87 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52738459; called by muse, mutect2, varscan2
- FITM2 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 60/106 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67679173; called by muse, mutect2, varscan2
- FKBP6 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.159); catalogued as COSV99333727; called by muse, mutect2, varscan2
- FKTN | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 32/43 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV99795271; called by muse, mutect2, varscan2
- FLNB | c.4634G>A p.R1545Q | Missense Mutation (SNP) | VAF 60/131 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs760317090, COSV99911893; called by muse, mutect2, varscan2
- FLT3 | c.2859G>A p.A953= | Splice Region (SNP) | VAF 21/54 reads (39%) | catalogued as rs751656163, COSV99607463; called by muse, mutect2, varscan2
- FLT3 | c.1117T>C p.F373L | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as rs1274622827, COSV99607465; called by muse, mutect2, varscan2
- FLVCR2 | c.1402C>G p.P468A | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99471066; called by muse, mutect2, varscan2
- FOXP1 | c.1766C>T p.S589F | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.76); catalogued as COSV100561106; called by muse, mutect2, varscan2
- FOXP2 | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.277); catalogued as rs1366555549, COSV100646263, COSV100646655; called by muse, mutect2, varscan2
- FRAS1 | c.9054G>A p.W3018* | Nonsense Mutation (SNP) | VAF 16/75 reads (21%) | catalogued as COSV99348490; called by muse, mutect2, varscan2
- FREM2 | c.5660C>T p.P1887L | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV99746973; called by muse, mutect2, varscan2
- FRMPD2 | c.1467T>G p.S489R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV100563539; called by muse, mutect2, varscan2
- FRY | c.2753A>T p.Y918F | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100968823; called by muse, mutect2, varscan2
- FSIP1 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.726); catalogued as rs1363704414, COSV63226886; called by muse, mutect2, varscan2
- FSTL5 | c.1774G>A p.G592R | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); catalogued as COSV60213164; called by muse, mutect2, varscan2
- FSTL5 | c.459A>T p.L153F | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100052949; called by muse, mutect2, varscan2
- FUS | c.857C>T p.T286I | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99568360; called by muse, mutect2, varscan2
- FXYD6 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.906); catalogued as COSV52804597; called by muse, mutect2, varscan2
- GABBR1 | c.2605G>A p.E869K | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.339); catalogued as COSV100589477; called by muse, mutect2, varscan2
- GABRA4 | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99973543; called by muse, mutect2, varscan2
- GABRP | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs770947239, COSV54665494; called by muse, mutect2, varscan2
- GALNT14 | c.1487G>A p.G496E | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.02); catalogued as COSV100204101; called by muse, varscan2
- GALNT17 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as rs751577191, COSV61164917; called by muse, mutect2, varscan2
- GALNT5 | c.1474C>T p.H492Y | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); catalogued as COSV99374864; called by muse, mutect2, varscan2
- GALNTL5 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as COSV101217696; called by muse, mutect2, varscan2
- GALNTL6 | c.1235C>T p.T412M | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs755485297, COSV101560119, COSV101560222; called by muse, mutect2, varscan2
- GBA3 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV101545474; called by muse, mutect2, varscan2
- GDPD2 | c.797T>C p.V266A | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV100978550, COSV100978576; called by muse, mutect2, varscan2
- GEMIN5 | c.1891C>T p.P631S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs1404416537, COSV99593602; called by muse, mutect2, varscan2
- GIMAP7 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57959691; called by muse, mutect2, varscan2
- GJB1 | c.132G>A p.W44* | Nonsense Mutation (SNP) | VAF 22/24 reads (92%) | catalogued as CM004104, CM1212945, COSV62139798, COSV62139848; called by muse, mutect2, varscan2
- GLB1L2 | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 33/40 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60277422; called by muse, mutect2, varscan2
- GLCE | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as COSV55944310, COSV99962342; called by muse, mutect2, varscan2
- GLRB | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as rs547823780, COSV100029493; called by muse, mutect2, varscan2
- GLRX3 | c.523C>T p.Q175* | Nonsense Mutation (SNP) | VAF 32/67 reads (48%) | catalogued as COSV58693306; called by muse, mutect2, varscan2
- GMDS | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.583); catalogued as COSV66418018; called by muse, mutect2, varscan2
- GMDS | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101071484; called by muse, mutect2, varscan2
- GNAI2 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV99806826; called by muse, mutect2, varscan2
- GNB5 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.043); catalogued as rs745575012, COSV99953133; called by muse, mutect2, varscan2
- GPA33 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 68/73 reads (93%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as rs774631325, COSV63300052; called by muse, mutect2, varscan2
- GPHN | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.981); catalogued as COSV100015450, COSV100017015; called by muse, mutect2, varscan2
- GPR149 | c.134T>C p.F45S | Missense Mutation (SNP) | VAF 49/86 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV101078130; called by muse, mutect2, varscan2
- GPR182 | c.327G>A p.W109* | Nonsense Mutation (SNP) | VAF 25/48 reads (52%) | catalogued as rs575072551, COSV100267643; called by muse, mutect2, varscan2
- GPR27 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as COSV99816234; called by muse, mutect2, varscan2
- GPT2 | c.982T>C p.S328P | Missense Mutation (SNP) | VAF 36/44 reads (82%) | SIFT tolerated (0.05); PolyPhen benign (0.117); catalogued as COSV100412795; called by muse, mutect2, varscan2
- GRB7 | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV100485383; called by muse, mutect2, varscan2
- GRIA2 | c.2482A>T p.M828L | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.869); catalogued as COSV99643151; called by muse, mutect2, varscan2
- GRID2 | c.2508T>A p.C836* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV99937574; called by muse, mutect2, varscan2
- GRIK4 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs138617238; called by muse, mutect2, varscan2
- GRIN2A | c.2989G>A p.E997K | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.992); catalogued as COSV58024179; called by muse, mutect2, varscan2
- GRIN2D | c.2171G>A p.S724N | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as COSV99615920; called by muse, mutect2, varscan2
- GRIP1 | c.2203G>A p.E735K (on ENST00000359742 / NM_001379345.1; = p.E683K on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as COSV99668129; called by muse, varscan2
- GRIP1 | c.2156G>A p.R719Q (on ENST00000359742 / NM_001379345.1; = p.R667Q on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs762131350, COSV54042639; called by muse, varscan2
- GRIP1 | c.2087C>T p.P696L (on ENST00000359742 / NM_001379345.1; = p.P644L on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV99668141; called by muse, mutect2, varscan2
- GSTCD | c.1343T>C p.F448S (on ENST00000360505 / NM_001031720.3; = p.F361S on NM_024751.3) | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100853780; called by muse, mutect2, varscan2
- GTF2IRD2B | c.1978C>T p.L660F | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100441064; called by muse, mutect2, varscan2
- GTPBP1 | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as rs940326206, COSV99322941; called by muse, mutect2, varscan2
- GUCA1A | c.447G>A p.G149= | Splice Region (SNP) | VAF 28/79 reads (35%) | catalogued as COSV99273818; called by muse, mutect2, varscan2
- GYS1 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.129); catalogued as rs778215783, COSV99620453; called by muse, mutect2, varscan2
- H1-6 | c.586C>T p.H196Y | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs200191053, COSV100619486; called by muse, mutect2, varscan2
- HBS1L | c.1073G>A p.G358E | Missense Mutation (SNP) | VAF 28/31 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1248739621, COSV100892509, COSV63201665; called by muse, mutect2, varscan2
- HCAR1 | c.952C>T p.L318F | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as rs772862696, COSV100811472; called by muse, mutect2, varscan2
- HCFC2 | c.278A>G p.Y93C | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV99982896; called by muse, mutect2, varscan2
- HCRTR1 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 72/168 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.636); catalogued as COSV101036111; called by muse, mutect2, varscan2
- HEATR5B | c.4387G>A p.E1463K | Missense Mutation (SNP) | VAF 68/147 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as COSV99248357; called by muse, mutect2, varscan2
- HECTD1 | c.4973C>T p.S1658F | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV101237304; called by muse, mutect2, varscan2
- HECTD4 | c.4694C>T p.S1565L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.997); catalogued as COSV101106753; called by muse, mutect2, varscan2
- HECW1 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 63/89 reads (71%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV67832503; called by muse, mutect2, varscan2
- HECW2 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 86/211 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53678481; called by muse, mutect2, varscan2
- HEG1 | c.2012C>T p.S671F | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs1211143758, COSV60759166; called by muse, varscan2
- HEPHL1 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV59894899; called by muse, mutect2, varscan2
- HIBADH | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1562652353, COSV99606910; called by muse, mutect2, varscan2
- HIPK1 | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100478488, COSV61248065; called by muse, mutect2, varscan2
- HIPK3 | c.1843G>A p.G615S | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.325); catalogued as COSV100305432; called by muse, mutect2, varscan2
- HIVEP2 | c.6545C>T p.P2182L | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.551); catalogued as COSV99171493; called by muse, mutect2, varscan2
- HK3 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.088); catalogued as rs866293926, COSV52844513; called by muse, mutect2, varscan2
- HK3 | c.1003G>A p.G335S | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV99457908; called by muse, mutect2, varscan2
- HPS3 | c.2318C>T p.T773I | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99937148; called by muse, mutect2, varscan2
- HR | c.2225C>T p.T742I | Missense Mutation (SNP) | VAF 58/70 reads (83%) | SIFT tolerated (0.19); PolyPhen benign (0.216); catalogued as COSV100455653; called by muse, mutect2, varscan2
- HSP90AA1 | c.1388T>C p.L463S | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99355026; called by muse, mutect2, varscan2
- HSPA12A | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.882); catalogued as COSV100979715; called by muse, mutect2, varscan2
- HTR1A | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); catalogued as COSV100108930; called by muse, mutect2, varscan2
- HTR1E | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 56/83 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV100540960; called by muse, mutect2, varscan2
- HTR5A | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99839458; called by muse, mutect2, varscan2
- HYAL2 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781999115, COSV100753822; called by muse, mutect2
- IBTK | c.3157C>T p.H1053Y | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV60392257; called by muse, mutect2, varscan2
- IGDCC4 | c.1699G>A p.G567S | Missense Mutation (SNP) | VAF 47/195 reads (24%) | SIFT tolerated (0.8); PolyPhen benign (0.044); catalogued as rs760971423, COSV100732711; called by muse, mutect2, varscan2
- IGFN1 | c.2399-1G>A p.X800_splice (on ENST00000295591 / NM_001367841.1; = p.X3257_splice on NM_001164586.2) | Splice Site (SNP) | VAF 30/34 reads (88%) | catalogued as rs776163795, COSV99811223; called by muse, varscan2
- IGHM | c.1375C>T p.L459F | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1476037466; called by muse, mutect2, varscan2
- IGHV2-70 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs561745237; called by muse, mutect2, varscan2
- IGHV3-16 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 93/212 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.783); catalogued as rs782709611; called by muse, mutect2, varscan2
- IGKV3-20 | c.251G>T p.S84I | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs537123757; called by muse, mutect2, varscan2
- IGKV3D-15 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs1234676001; called by muse, mutect2, varscan2
- IGLV2-33 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 113/246 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1489094975; called by muse, mutect2, varscan2
- IGSF1 | c.1844C>T p.P615L | Missense Mutation (SNP) | VAF 44/48 reads (92%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100811843; called by muse, mutect2, varscan2
- IGSF1 | c.1843C>T p.P615S | Missense Mutation (SNP) | VAF 47/51 reads (92%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs759679565, COSV100811845; called by muse, mutect2, varscan2
- IGSF10 | c.6073G>A p.D2025N | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99176716; called by muse, mutect2, varscan2
- IGSF21 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.368); catalogued as rs183577264, COSV99243806; called by muse, mutect2, varscan2
- IHH | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99838602; called by muse, mutect2, varscan2
- IL16 | c.1118T>C p.V373A | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV100267031; called by muse, mutect2, varscan2
- IL31RA | c.1489G>A p.G497R | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771896548, COSV99762845; called by muse, mutect2, varscan2
- IL36A | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99382056; called by muse, mutect2, varscan2
- ILDR2 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 128/148 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1360794311, COSV99613269; called by muse, mutect2, varscan2
- ILDR2 | c.822G>A p.M274I | Missense Mutation (SNP) | VAF 64/75 reads (85%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as rs1300461877, COSV99613271; called by muse, mutect2, varscan2
- IMPG2 | c.2653G>A p.E885K | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99514885; called by muse, mutect2, varscan2
- INPPL1 | c.3307C>T p.P1103S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99995884; called by muse, mutect2, varscan2
- INSYN2A | c.887G>A p.G296E | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.708); catalogued as COSV54738736; called by muse, mutect2, varscan2
- INTU | c.259C>T p.H87Y | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1473182580, COSV99611446, COSV99612285; called by muse, mutect2, varscan2
- INTU | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1227833863, COSV58871021; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INVS | c.2605G>A p.E869K | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.106); catalogued as rs755324664, COSV52439855; called by muse, mutect2, varscan2
- IPO13 | c.2486C>T p.P829L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV99664275; called by muse, mutect2, varscan2
- IQSEC1 | c.1672G>A p.G558R | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1049023791, COSV56224201, COSV99831357; called by muse, mutect2, varscan2
- IRAG1 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as rs368142067; called by muse, mutect2, varscan2
- ISL1 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1474110808, COSV57931810; called by muse, varscan2
- ITGA11 | c.1993G>A p.D665N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV100240966; called by muse, mutect2, varscan2
- ITGA2 | c.2519G>A p.G840E | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1179271723, COSV99670278; called by muse, mutect2, varscan2
- ITGA4 | c.1360C>T p.R454W | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs201906563, COSV51998072; called by muse, mutect2, varscan2
- ITGA4 | c.2830C>T p.P944S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100183172; called by muse, mutect2, varscan2
- ITGA4 | c.2831C>T p.P944L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs370357165; called by muse, mutect2, varscan2
- ITGA7 | c.2995G>A p.A999T (on ENST00000555728; = p.A955T on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs182485135, COSV99144353; called by muse, mutect2, varscan2
- ITGA7 | c.2137G>A p.D713N (on ENST00000555728; = p.D669N on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.045); catalogued as rs1490372035, COSV57695496; called by muse, mutect2, varscan2
- ITGA8 | c.2827G>T p.E943* | Nonsense Mutation (SNP) | VAF 24/33 reads (73%) | catalogued as COSV100958896, COSV65226491; called by muse, mutect2, varscan2
- ITGAL | c.2621T>C p.V874A | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as COSV100776077; called by muse, mutect2, varscan2
- ITGAL | c.3080A>T p.Q1027L | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV100776078; called by muse, mutect2, varscan2
- ITGB3 | c.370A>C p.K124Q | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as COSV101457547; called by muse, mutect2, varscan2
- ITGBL1 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.258); catalogued as rs745378521, COSV66008382, COSV66011885; called by muse, mutect2, varscan2
- ITIH1 | c.824A>C p.N275T | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV99834961; called by muse, mutect2, varscan2
- ITPR2 | c.6616G>T p.E2206* | Nonsense Mutation (SNP) | VAF 33/119 reads (28%) | catalogued as rs768249218, COSV101189825; called by muse, mutect2, varscan2
- ITPR3 | c.7423G>A p.G2475S | Missense Mutation (SNP) | VAF 55/250 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100953584; called by muse, mutect2, varscan2
- ITPRID1 | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 42/63 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100085703, COSV100086339; called by muse, mutect2, varscan2
- KANSL1 | c.1385G>A p.R462Q | Missense Mutation (SNP) | VAF 56/242 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1159124298, COSV99294099; called by muse, varscan2
- KAT2A | c.1903A>G p.K635E | Missense Mutation (SNP) | VAF 83/203 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV99288032; called by muse, mutect2, varscan2
- KBTBD12 | c.1085G>A p.G362E | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0.031); catalogued as COSV59678942; called by muse, mutect2, varscan2
- KCNB2 | c.2234C>T p.S745L | Missense Mutation (SNP) | VAF 63/133 reads (47%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs557129070, COSV73052458; called by muse, mutect2, varscan2
- KCND2 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100473743; called by muse, mutect2, varscan2
- KCNG1 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as rs1462201003, COSV100856990; called by muse, mutect2, varscan2
- KCNH6 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.17); catalogued as COSV59001356; called by muse, mutect2, varscan2
- KCNK17 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs866557716, COSV64679584; called by muse, mutect2, varscan2
- KCTD20 | c.74T>C p.L25S | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV99535776; called by muse, mutect2, varscan2
- KDM4B | c.2933C>T p.S978F | Missense Mutation (SNP) | VAF 36/41 reads (88%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs267605545, COSV50213135; called by muse, mutect2, varscan2
- KERA | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.298); catalogued as rs911725917, COSV57131851; called by muse, mutect2, varscan2
- KIAA0319 | c.2693C>T p.A898V | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as rs1411030205, COSV100985221; called by muse, mutect2, varscan2
- KIAA0408 | c.866G>A p.W289* | Nonsense Mutation (SNP) | VAF 44/76 reads (58%) | catalogued as COSV100846790; called by muse, mutect2, varscan2
- KIAA0895L | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.01); catalogued as rs1438549305, COSV99220392; called by muse, mutect2, varscan2
- KIAA1217 | c.1907C>T p.P636L | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as COSV100286230; called by muse, mutect2, varscan2
- KIAA1217 | c.5533G>A p.G1845R | Missense Mutation (SNP) | VAF 40/58 reads (69%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as COSV100286232; called by muse, mutect2, varscan2
- KIAA1328 | c.1535C>T p.S512F | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99693317; called by muse, mutect2, varscan2
- KIDINS220 | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 83/174 reads (48%) | catalogued as rs200360669, COSV56756012, COSV99874990; called by muse, mutect2, varscan2
- KIF1B | c.1735G>A p.E579K (on ENST00000377086 / NM_001365952.1; = p.E533K on NM_015074.3) | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99822550; called by muse, mutect2, varscan2
- KIF23 | c.2011C>T p.R671W | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs377162847, CM1314893; called by muse, mutect2, varscan2
- KIF4B | c.3110A>G p.Q1037R | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV101469196; called by muse, mutect2, varscan2
- KIR3DL2 | c.1310G>A p.R437K | Missense Mutation (SNP) | VAF 120/313 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV54391974, COSV99551778; called by muse, mutect2, varscan2
- KIR3DL3 | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 89/184 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52551039; called by muse, mutect2, varscan2
- KLHDC7A | c.710G>T p.G237V | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV101272729; called by muse, mutect2, varscan2
- KLHL14 | c.1160G>A p.G387E | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63831946; called by muse, mutect2, varscan2
- KLHL3 | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1177111958, COSV100552925, COSV100553728; called by muse, mutect2, varscan2
- KLHL30 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1266023829, COSV100013988; called by muse, mutect2, varscan2
- KLHL6 | c.1101G>A p.W367* | Nonsense Mutation (SNP) | VAF 58/145 reads (40%) | catalogued as COSV100384331; called by muse, mutect2, varscan2
- KLHL6 | c.1100G>A p.W367* | Nonsense Mutation (SNP) | VAF 54/141 reads (38%) | catalogued as rs1320643877, COSV100384348; called by muse, mutect2, varscan2
- KLHL8 | c.938G>T p.R313M | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99911239; called by muse, mutect2, varscan2
- KLK5 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.218); catalogued as rs748294116, COSV60449437; called by muse, mutect2, varscan2
- KLK9 | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99143886; called by muse, mutect2, varscan2
- KMT2A | c.3341C>T p.S1114L | Missense Mutation (SNP) | VAF 51/84 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100628056; called by muse, mutect2, varscan2
- KMT2D | c.7250C>T p.S2417F | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99977836; called by muse, mutect2, varscan2
- KRBA1 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs752532041, COSV55444886; called by muse, mutect2, varscan2
- KRT16 | c.1024G>A p.G342S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.206); catalogued as rs1161722974, COSV100052817; called by muse, mutect2, varscan2
- KRT34 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101222561; called by muse, mutect2, varscan2
- KRT83 | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 56/70 reads (80%) | catalogued as COSV99531349; called by muse, mutect2, varscan2
- KRT9 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 63/142 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.089); catalogued as COSV99879022; called by muse, mutect2, varscan2
- KRT9 | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.991); catalogued as rs1433109196, COSV99879023; called by muse, mutect2
- KRTAP10-5 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as rs1555924555, COSV100552747, COSV59976695; called by muse, mutect2, varscan2
- KRTAP9-2 | c.397A>C p.N133H | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.477); catalogued as COSV100893121; called by muse, mutect2, varscan2
- LAMA5 | c.4300G>A p.G1434R | Missense Mutation (SNP) | VAF 55/88 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99438212; called by muse, mutect2, varscan2
- LARGE1 | c.1991G>A p.R664K | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV100504675; called by muse, mutect2, varscan2
- LARP1 | c.1052G>C p.G351A (on ENST00000518297 / NM_033551.3; = p.G274A on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV100303468; called by muse, mutect2, varscan2
- LCLAT1 | c.755A>T p.D252V | Missense Mutation (SNP) | VAF 73/213 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1417642920, COSV100473538; called by muse, mutect2, varscan2
- LCORL | c.504T>A p.F168L | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100481588; called by muse, mutect2, varscan2
- LCTL | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as rs770296735, COSV58421416; called by muse, mutect2, varscan2
- LDB1 | c.145C>T p.P49S (on ENST00000425280 / NM_001321612.2; = p.P13S on NM_003893.5) | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.46); catalogued as rs770225174, COSV100756320; called by muse, mutect2, varscan2
- LDHAL6A | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1331167219, COSV99323722; called by muse, mutect2, varscan2
- LGALS3BP | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as rs1180145404, COSV99431377; called by muse, mutect2, varscan2
- LGI2 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV101180760; called by muse, mutect2, varscan2
- LHX8 | c.1012C>T p.L338F | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99633126; called by muse, mutect2, varscan2
- LIG3 | c.2467C>T p.P823S | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0.017); catalogued as COSV99252193; called by muse, mutect2, varscan2
- LIG4 | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV63596836; called by muse, mutect2, varscan2
- LILRA4 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.953); catalogued as rs767985779, COSV99392877; called by muse, mutect2, varscan2
- LILRA4 | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as rs867832303, COSV99392913; called by muse, mutect2, varscan2
- LIMA1 | c.2162C>T p.T721I | Missense Mutation (SNP) | VAF 53/82 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as COSV100372228; called by muse, mutect2, varscan2
- LINGO2 | c.857G>A p.S286N | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT tolerated (0.21); PolyPhen benign (0.109); catalogued as rs1340006966, COSV100430184, COSV100431371; called by muse, varscan2
- LINGO2 | c.760C>T p.L254F | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100430185; called by muse, varscan2
- LINGO2 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1265499185, COSV100430189; called by muse, mutect2, varscan2
- LOXL2 | c.797C>T p.T266I | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV101207744; called by muse, mutect2, varscan2
- LPA | c.3931G>A p.E1311K | Missense Mutation (SNP) | VAF 37/48 reads (77%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.934); catalogued as COSV60317240; called by muse, mutect2, varscan2
- LPP | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV57113145; called by muse, mutect2, varscan2
- LRCH3 | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV100604970; called by muse, mutect2, varscan2
- LRFN1 | c.1270G>A p.A424T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.055); catalogued as COSV99952652; called by muse, mutect2, varscan2
- LRP1 | c.10130G>A p.G3377E | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99674579; called by muse, mutect2, varscan2
- LRP1B | c.13135T>A p.F4379I | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV101253007; called by muse, mutect2, varscan2
- LRP2 | c.4102C>T p.P1368S | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1288465067, COSV99786681; called by muse, mutect2, varscan2
- LRRC37A3 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.402); catalogued as COSV100140869; called by mutect2, varscan2
- LRRC49 | c.1704G>A p.R568= | Splice Region (SNP) | VAF 36/91 reads (40%) | catalogued as COSV99536974; called by muse, varscan2
- LRRC49 | c.1739G>A p.G580E | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as rs1450128270, COSV53008314; called by muse, varscan2
- LRRC4B | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.786); catalogued as rs1228571137, COSV100975842; called by muse, mutect2, varscan2
- LRRC55 | c.594G>A p.W198* | Nonsense Mutation (SNP) | VAF 30/114 reads (26%) | catalogued as COSV101546704; called by muse, mutect2, varscan2
- LRRCC1 | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as COSV64485655; called by muse, mutect2, varscan2
- LRRN3 | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.414); catalogued as rs754492491, COSV100068054; called by muse, mutect2, varscan2
- LRRN4 | c.1220C>T p.S407F | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as rs1327604519, COSV101125371; called by muse, mutect2, varscan2
- LTA4H | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 25/76 reads (33%) | catalogued as COSV99956929; called by muse, mutect2, varscan2
- LTBP2 | c.4750G>A p.D1584N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99999766; called by muse, mutect2, varscan2
- LTBP4 | c.2233G>A p.G745R (on ENST00000308370 / NM_001042544.1; = p.G708R on NM_003573.2) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99180530; called by muse, mutect2, varscan2
- LTBP4 | c.4814G>A p.R1605H (on ENST00000308370 / NM_001042544.1; = p.R1568H on NM_003573.2) | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.615); catalogued as rs777450656, COSV52577027; called by muse, mutect2, varscan2
- LUZP1 | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 6/74 reads (8%) | catalogued as COSV56505069; called by muse, mutect2
- LUZP2 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1215809915, COSV100420969, COSV61199599; called by muse, mutect2, varscan2
- LY75 | c.3019G>A p.E1007K | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.543); catalogued as COSV99716036; called by muse, mutect2, varscan2
- LZTFL1 | c.64C>G p.R22G | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV56110793, COSV56112075, COSV99944738; called by muse, mutect2, varscan2
- MAB21L4 | c.686G>A p.R229K (on ENST00000388934 / NM_001085437.3; = p.R61K on NM_024861.4) | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1403349008, COSV100278403; called by muse, mutect2
- MACROD2 | c.973G>A p.E325K (on ENST00000642719; = p.E297K on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV54039562; called by muse, mutect2, varscan2
- MAGEB10 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as COSV63312745; called by muse, mutect2, varscan2
- MAGEB16 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.484); catalogued as COSV101303278; called by muse, mutect2, varscan2
- MAGIX | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 38/44 reads (86%) | SIFT tolerated (0.48); PolyPhen benign (0.121); catalogued as COSV100891841; called by muse, mutect2, varscan2
- MAML1 | c.2072C>T p.S691F | Missense Mutation (SNP) | VAF 54/90 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as rs1251915114, COSV99482906; called by muse, mutect2, varscan2
- MAN1C1 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs574993256, COSV99847841; called by muse, mutect2, varscan2
- MAP10 | c.2263G>A p.V755I | Missense Mutation (SNP) | VAF 93/104 reads (89%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as COSV101406437; called by muse, mutect2, varscan2
- MAP1A | c.7661C>T p.P2554L | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV100288122; called by muse, mutect2, varscan2
- MAP1LC3C | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 153/176 reads (87%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as COSV61803501; called by muse, mutect2, varscan2
- MAP4K3 | c.1294C>T p.P432S | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.133); catalogued as COSV55712685; called by muse, mutect2, varscan2
- MAST1 | c.3259G>A p.E1087K | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as rs1328394250, COSV99262371; called by muse, mutect2, varscan2
- MAST4 | c.1535C>T p.T512I (on ENST00000403625 / NM_001164664.2; = p.T323I on NM_015183.3) | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99842988; called by muse, mutect2, varscan2
- MAT1A | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 84/171 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); catalogued as COSV100944388; called by muse, mutect2, varscan2
- MBL2 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64757897; called by muse, mutect2, varscan2
- MCM10 | c.1384G>A p.G462R (on ENST00000484800 / NM_182751.3; = p.G461R on NM_018518.5) | Missense Mutation (SNP) | VAF 52/73 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs887958351, COSV66333267; called by muse, mutect2, varscan2
- MCM2 | c.2077G>A p.E693K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs773395316, COSV99412835; called by muse, varscan2
- MCTP1 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100386364; called by muse, mutect2, varscan2
- MCTP2 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs1056652608, COSV100537225; called by muse, mutect2, varscan2
- MDGA1 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99776288; called by muse, varscan2
- MECOM | c.2830C>T p.P944S (on ENST00000468789 / NM_001105078.4; = p.P1132S on NM_004991.4) | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.051); catalogued as rs778470697, COSV99244137; called by muse, mutect2, varscan2
- MECOM | c.2543G>A p.R848Q (on ENST00000468789 / NM_001105078.4; = p.R1036Q on NM_004991.4) | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs756700169, COSV52959825, COSV52966120; called by muse, mutect2, varscan2
- MECOM | c.2180G>A p.R727Q (on ENST00000468789 / NM_001105078.4; = p.R915Q on NM_004991.4) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs1266973210, COSV52959477; called by muse, mutect2, varscan2
- MED12L | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.894); catalogued as COSV99851653; called by muse, mutect2, varscan2
- MED23 | c.2857C>T p.P953S | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100644782; called by muse, mutect2, varscan2
- METTL21C | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs372296617; called by muse, mutect2, varscan2
- MFAP3 | c.424T>C p.F142L | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as COSV100491505; called by muse, mutect2, varscan2
- MGAM | c.3272C>T p.P1091L | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72073904; called by muse, mutect2, varscan2
- MGAT4C | c.829T>A p.L277I | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV100152688; called by muse, mutect2, varscan2
- MGME1 | c.77T>G p.V26G | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100891336; called by muse, mutect2, varscan2
- MIA2 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99696623; called by muse, mutect2, varscan2
- MINAR1 | c.1981C>T p.P661S | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV59583187; called by muse, mutect2, varscan2
- MLIP | c.166C>T p.L56F | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99228558; called by muse, mutect2, varscan2
- MMP16 | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs768109261, COSV54176168; called by muse, mutect2, varscan2
- MMP21 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.334); catalogued as rs1482655851, COSV100916667; called by muse, mutect2, varscan2
- MMRN1 | c.1307C>T p.S436L | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV53339383; called by muse, mutect2, varscan2
- MOV10L1 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV99432783; called by muse, mutect2, varscan2
- MOXD1 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100381278; called by muse, mutect2, varscan2
- MPIG6B | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.895); catalogued as rs1308000476, COSV65389546; called by muse, mutect2, varscan2
- MPIG6B | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.928); catalogued as COSV101008042; called by muse, mutect2, varscan2
- MPO | c.991A>T p.N331Y | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99832286; called by muse, mutect2, varscan2
- MPPED2 | c.13A>T p.I5F | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as COSV100813107; called by muse, mutect2, varscan2
- MRGPRX2 | c.857G>A p.R286K | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as COSV100316634; called by muse, mutect2, varscan2
- MROH5 | c.1642G>T p.V548F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV71300390; called by muse, mutect2
- MROH9 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 60/74 reads (81%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV100882691, COSV63012231; called by muse, mutect2, varscan2
- MRPS23 | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 39/67 reads (58%) | catalogued as COSV100551412; called by muse, mutect2, varscan2
- MS4A4A | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV100557715; called by muse, mutect2, varscan2
- MSR1 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as rs200576411, COSV100026618; called by muse, mutect2, varscan2
- MSRB3 | c.467G>A p.R156K | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV57588987, COSV57589730; called by muse, mutect2, varscan2
- MTBP | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV100011845; called by muse, mutect2, varscan2
- MTHFD2L | c.457G>C p.V153L (on ENST00000395759 / NM_001144978.2; = p.V95L on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV100305839; called by muse, mutect2, varscan2
- MUC13 | c.1498C>T p.P500S | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60701619; called by muse, mutect2, varscan2
- MUC15 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs375176901, COSV99846190, COSV99846440; called by muse, mutect2, varscan2
- MUC16 | c.29548G>A p.D9850N | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV67461333; called by muse, mutect2, varscan2
- MUC16 | c.18545G>A p.G6182E | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.053); catalogued as rs866782070, COSV67442014; called by muse, mutect2, varscan2
- MUC16 | c.12946C>T p.Q4316* | Nonsense Mutation (SNP) | VAF 18/26 reads (69%) | catalogued as rs753800371, COSV101198306; called by muse, mutect2, varscan2
- MUC16 | c.10439G>A p.G3480E | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.006); catalogued as COSV67458733; called by muse, mutect2, varscan2
- MUC16 | c.3128G>A p.G1043E | Missense Mutation (SNP) | VAF 47/59 reads (80%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.08); catalogued as COSV101198309; called by muse, mutect2, varscan2
- MUC17 | c.3482C>T p.P1161L | Missense Mutation (SNP) | VAF 287/447 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs778632866, COSV100071739; called by muse, mutect2, varscan2
- MUC17 | c.12131C>T p.P4044L | Missense Mutation (SNP) | VAF 92/154 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100071741; called by muse, mutect2, varscan2
- MUC4 | c.2704G>A p.A902T | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.494); catalogued as COSV62129349; called by muse, mutect2, varscan2
- MXRA5 | c.5167C>T p.P1723S | Missense Mutation (SNP) | VAF 22/23 reads (96%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV54227847; called by muse, mutect2, varscan2
- MYBPC2 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs779252873, COSV100731604; called by muse, mutect2, varscan2
- MYBPC2 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 2/16 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV63098906; called by muse, mutect2
- MYCBPAP | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs914409018, COSV100087737; called by muse, mutect2, varscan2
- MYCBPAP | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60409509; called by muse, mutect2, varscan2
- MYH1 | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 78/108 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs1320620513, COSV99874986; called by muse, mutect2, varscan2
- MYH1 | c.1095G>A p.M365I | Missense Mutation (SNP) | VAF 64/80 reads (80%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as COSV56852997; called by muse, mutect2, varscan2
- MYH10 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99344183; called by muse, mutect2, varscan2
- MYH11 | c.5386G>A p.E1796K | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV100257792; called by muse, mutect2, varscan2
- MYH11 | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100257793; called by muse, mutect2, varscan2
- MYH13 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 58/82 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99352418; called by muse, mutect2, varscan2
- MYH13 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 54/70 reads (77%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99352424; called by muse, mutect2, varscan2
- MYH6 | c.5002G>A p.D1668N | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs200884672, COSV62450523; called by muse, mutect2, varscan2
- MYH8 | c.3796G>A p.E1266K | Missense Mutation (SNP) | VAF 49/71 reads (69%) | SIFT tolerated (0.29); PolyPhen benign (0.102); catalogued as COSV101238236; called by muse, mutect2, varscan2
- MYL1 | c.168G>T p.K56N | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs138478671; called by muse, mutect2, varscan2
- MYLK | c.2860C>T p.R954C | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs749847711, COSV60609949; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYLK | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs767114476, COSV60608743; called by muse, mutect2, varscan2
- MYO1A | c.887G>A p.G296E | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100270606; called by muse, mutect2, varscan2
- MYO5A | c.4409A>G p.E1470G | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV100697331; called by muse, mutect2, varscan2
- MYO5A | c.4408G>A p.E1470K | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV100697332; called by muse, mutect2, varscan2
- MYO5C | c.3805G>A p.E1269K | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV55911854, COSV99954128; called by muse, mutect2, varscan2
- MYO7A | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV101289047; called by muse, mutect2, varscan2
- MYOCD | c.2606C>T p.S869L | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as COSV58496972; called by muse, mutect2, varscan2
- MYOF | c.4341G>A p.E1447= | Splice Region (SNP) | VAF 34/88 reads (39%) | catalogued as rs1175030719, COSV100825261; called by muse, mutect2, varscan2
- MYOZ1 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); catalogued as rs1422703015, COSV100831775; called by muse, mutect2, varscan2
- MYPN | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100589567, COSV62736032; called by muse, mutect2, varscan2
- MYRIP | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.657); catalogued as COSV100218374; called by muse, mutect2, varscan2
- MYRIP | c.1388C>T p.S463F | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.299); catalogued as COSV100218375; called by muse, mutect2, varscan2
- MYT1L | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1295853812, COSV101218972, COSV67726822; called by muse, mutect2, varscan2
- NACA2 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs752237901, COSV101478527; called by muse, mutect2, varscan2
- NAMPT | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99747657; called by muse, mutect2, varscan2
- NBEA | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 26/70 reads (37%) | catalogued as COSV100077054; called by muse, mutect2, varscan2
- NCOA3 | c.1931C>T p.S644L | Missense Mutation (SNP) | VAF 100/177 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); catalogued as rs1229549236, COSV100507182, COSV100507475; called by muse, mutect2, varscan2
- NEB | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV50813600, COSV99415284; called by muse, mutect2, varscan2
- NECTIN4 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 147/165 reads (89%) | SIFT tolerated (0.48); PolyPhen benign (0.153); catalogued as rs200474573, COSV100919823; called by muse, mutect2, varscan2
- NEDD4L | c.2873G>A p.R958Q (on ENST00000400345 / NM_001144967.3; = p.R938Q on NM_015277.6) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); catalogued as rs777624478, COSV56845561; called by muse, mutect2, varscan2
- NEFH | c.1486G>A p.G496R | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.034); catalogued as COSV100151267, COSV60216358; called by muse, mutect2, varscan2
- NEK10 | c.2403G>T p.L801F | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV99834799; called by muse, mutect2, varscan2
- NELFCD | c.173A>G p.H58R (on ENST00000602795; = p.H40R on NM_198976.4) | Missense Mutation (SNP) | VAF 61/104 reads (59%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs766699656, COSV100682714; called by muse, mutect2, varscan2
- NEUROD4 | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 176/399 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); catalogued as rs1427344225, COSV99669723; called by muse, mutect2, varscan2
- NEXMIF | c.2329C>T p.H777Y | Missense Mutation (SNP) | VAF 49/58 reads (84%) | SIFT tolerated (0.12); PolyPhen benign (0.346); catalogued as COSV50145813; called by muse, mutect2, varscan2
- NFATC4 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 75/205 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV99144437; called by muse, mutect2, varscan2
- NFE2 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.147); catalogued as rs368417462; called by muse, mutect2, varscan2
- NGEF | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.572); catalogued as rs767569783, COSV50956835, COSV50965403; called by muse, mutect2, varscan2
- NHLRC1 | c.751C>T p.L251F | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as rs374327275, COSV100513568; called by muse, mutect2, varscan2
- NIBAN1 | c.2365C>T p.P789S | Missense Mutation (SNP) | VAF 193/221 reads (87%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.088); catalogued as COSV62284224; called by muse, mutect2, varscan2
- NID2 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1005521920, COSV99355986; called by muse, mutect2, varscan2
- NLGN2 | c.847C>T p.L283= | Splice Region (SNP) | VAF 17/21 reads (81%) | catalogued as COSV100259279; called by muse, mutect2, varscan2
- NLRC3 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100072468; called by mutect2, varscan2
- NLRC5 | c.2572G>A p.D858N | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0.155); catalogued as COSV52659326; called by muse, mutect2, varscan2
- NLRP10 | c.1922G>A p.G641E | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); catalogued as COSV100149489; called by muse, mutect2, varscan2
- NLRP11 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs866104256, COSV64086222; called by muse, mutect2, varscan2
- NLRP12 | c.2794G>A p.G932S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.388); catalogued as COSV100144895, COSV100144982; called by muse, mutect2, varscan2
- NLRP5 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV66764090; called by muse, varscan2
- NLRP5 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.1); catalogued as rs780828462, COSV66763274, COSV66766342; called by muse, varscan2
- NLRP8 | c.1735G>A p.V579M | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.133); catalogued as COSV99404769; called by muse, mutect2, varscan2
- NLRP9 | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as rs766285653, COSV60468907; called by muse, mutect2, varscan2
- NLRP9 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV100242612, COSV100243374; called by muse, mutect2, varscan2
- NOBOX | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769328958, COSV56192923; called by muse, mutect2, varscan2
- NOS1 | c.883A>T p.K295* | Nonsense Mutation (SNP) | VAF 27/58 reads (47%) | catalogued as COSV100500084; called by muse, mutect2, varscan2
- NOTCH4 | c.3602G>A p.G1201E | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100900379; called by muse, mutect2, varscan2
- NOX5 | c.2059G>A p.A687T | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99533341; called by muse, mutect2, varscan2
- NPAP1 | c.752A>T p.H251L | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.307); catalogued as COSV100274818; called by muse, mutect2, varscan2
- NPAS1 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as rs965911315, COSV99451326; called by muse, mutect2, varscan2
- NPM2 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.726); catalogued as rs1434666769, COSV99235652; called by muse, mutect2, varscan2
- NPR3 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1226931003, COSV99422337; called by muse, mutect2, varscan2
- NR2C2 | c.848C>T p.S283F (on ENST00000393102; = p.S302F on NM_003298.5) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100038283; called by muse, mutect2, varscan2
- NRG1 | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 24/28 reads (86%) | catalogued as COSV99827728; called by muse, mutect2, varscan2
1,375 further variants in this file (634 protein-altering or splice-affecting, 690 silent, 51 other) are not listed here.
